MMRF case MMRF_1535 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/2b42b005-032c-477c-9503-8c0d36b79495

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.3 years (23,848 days); ISS stage: I; Days to last known disease status: 1,071 days (2.9 years); Days to last follow up: 1,071 days (2.9 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 154 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 366 days (1.0 years); Days to treatment end: 394 days (1.1 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,071.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -23 (ECOG 2): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.83 mg/dL; Immunoglobulin G 19.2 g/L; Immunoglobulin A 1.42 g/L; Immunoglobulin M 0.7 g/L; Beta 2 Microglobulin 2.7 µg/mL; Lactate Dehydrogenase 6.62 µkat/L; Hemoglobin 5.21 mmol/L; Leukocytes 9.3 ×10⁹/L; Absolute Neutrophil 7.25 ×10⁹/L; Platelets 628 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.15 mmol/L; Albumin 38 g/L; Total Protein 7.8 g/dL; Glucose 7.15 mmol/L; C-Reactive Protein 0.07 mg/dL.
- Day 92 (ECOG 2): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.18 mg/dL; Immunoglobulin G 7.74 g/L; Immunoglobulin A 2.27 g/L; Immunoglobulin M 0.61 g/L; Hemoglobin 4.4 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.47 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 1.98 mmol/L; Albumin 30 g/L; Total Protein 5.8 g/dL; Glucose 7.04 mmol/L.
- Day 154 (ECOG 3): Hemoglobin 4.34 mmol/L; Leukocytes 9.2 ×10⁹/L; Absolute Neutrophil 7.54 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.1 mmol/L; Albumin 25 g/L; Total Protein 4.8 g/dL; Glucose 5.23 mmol/L.
- Day 246 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 3.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.29 mg/dL; Immunoglobulin G 7.69 g/L; Immunoglobulin A 1.54 g/L; Immunoglobulin M 0.7 g/L; Hemoglobin 4.71 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.27 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 177 µmol/L; Blood Urea Nitrogen 17.9 mmol/L; Calcium 1.95 mmol/L; Albumin 28 g/L; Total Protein 5.8 g/dL; Glucose 4.84 mmol/L.
- Day 362 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 3.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.98 mg/dL; Immunoglobulin G 8.94 g/L; Immunoglobulin A 2.02 g/L; Immunoglobulin M 0.63 g/L; Hemoglobin 5.21 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 265 ×10⁹/L.
- Day 394: Hemoglobin 5.39 mmol/L; Leukocytes 5.9 ×10⁹/L; Platelets 242 ×10⁹/L.
- Day 464: Serum Free Immunoglobulin Light Chain, Kappa 5.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 2.23 g/L; Immunoglobulin M 0.86 g/L; Beta 2 Microglobulin 0.7 µg/mL; Hemoglobin 6.2 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 6.95 ×10⁹/L; Platelets 308 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.1 mmol/L; Albumin 30 g/L; Total Protein 6.2 g/dL; Glucose 11.4 mmol/L.
- Day 608 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 6.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.32 mg/dL; Immunoglobulin G 12.4 g/L; Immunoglobulin A 2.84 g/L; Immunoglobulin M 1.21 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 6.59 ×10⁹/L; Platelets 316 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.1 mmol/L; Albumin 32 g/L; Total Protein 6.7 g/dL; Glucose 10.4 mmol/L.
- Day 701 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.78 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 2.38 g/L; Immunoglobulin M 1.28 g/L; Hemoglobin 7.13 mmol/L; Leukocytes 9.4 ×10⁹/L; Absolute Neutrophil 7.05 ×10⁹/L; Platelets 257 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.15 mmol/L; Albumin 35 g/L; Total Protein 6.8 g/dL; Glucose 7.48 mmol/L.
- Day 793 (ECOG 0): M Protein 0.3 g/dL; Immunoglobulin G 12.2 g/L; Immunoglobulin A 2.41 g/L; Immunoglobulin M 1.41 g/L; Hemoglobin 6.63 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 5.92 ×10⁹/L; Platelets 278 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 7.1 g/dL; Glucose 11.4 mmol/L.
- Day 853 (ECOG 2): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.98 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 2.53 g/L; Immunoglobulin M 1.42 g/L; Beta 2 Microglobulin 0.9 µg/mL; Hemoglobin 6.82 mmol/L; Leukocytes 9.5 ×10⁹/L; Absolute Neutrophil 7.13 ×10⁹/L; Platelets 322 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.15 mmol/L; Albumin 36 g/L; Total Protein 7.1 g/dL; Glucose 7.7 mmol/L.
- Day 1,002 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.77 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 2.31 g/L; Immunoglobulin M 1.2 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.88 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.13 mmol/L; Albumin 31 g/L; Total Protein 6.2 g/dL; Glucose 9.63 mmol/L.

Other clinical attributes
- Day -23: Weight: 90 kg; Height: 182 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1535_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -23 days.
- Sample MMRF_1535_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -23 days.
